CGCI case BLGSP-71-27-00513 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fa81c6c4-a72c-475b-837e-36ebbf5007dc

Demographics
Sex at birth: male; Race: white; Age at index: 57 years; Vital status: Dead; Days to death: 311 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 57.4 years (20,980 days); Year of diagnosis: 2017; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 311 days; Ann Arbor extranodal involvement: Yes; Sites of involvement: Bone marrow / Colon, NOS / Stomach / Pleura.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CODOX-M; Days to treatment start: 3 days; Days to treatment end: 3 days; Number of cycles: 1; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 3 days; Number of cycles: 1; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: CODOX-M; Days to treatment start: 41 days; Days to treatment end: 63 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: IVAC; Days to treatment start: 41 days; Days to treatment end: 63 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 63 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: DA-EPOCH; Days to treatment start: 104 days; Days to treatment end: 104 days; Number of cycles: 1; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 104 days; Days to treatment end: 104 days; Number of cycles: 1; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine + Rituximab; Initial disease status: Recurrent Disease; Days to treatment start: 268 days; Days to treatment end: 290 days; Number of cycles: 2; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 267 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 267 days.
- Days to follow up: 311 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD19 (IHC): Positive.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD3 (IHC): Negative.
- CD3 (IHC): Positive.
- CD30 (IHC): Negative.
- CD34 (IHC): Negative.
- CD45 (IHC): Positive.
- CD5 (IHC): Negative.
- IRF4 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Test (IHC): Positive; Specialized molecular test: CD38.
- Lactate Dehydrogenase 788 [Blood test normal range upper: 250].

Other clinical attributes
- Day 0: Weight: 75.2 kg; Height: 181.5 cm; BMI: 22.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-27-00513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-27-00513-01A-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-27-00513-01A-S1-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-27-00513-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-27-00513-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 127 days; Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 4; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Colon; Extranodal involvement site: Stomach; Extranodal involvement site: Pleura/Pleural Effusion.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 788; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD45.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD38.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: MUM1.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 13: Immunophenotypic analysis tested: CD34.
- Tests performed, Genetic testing results, Genetic testing result 14: Immunophenotypic analysis tested: Cyclin D1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: Yes; New tumor event radiation treatment: Yes.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event site other: subcarinal lymph node; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Ivac / codox-m; Pharma adjuvant cycles count: 2.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 1.
- Treatments, Treatment 3: Chemo end reporting period: Yes; Pharmaceutical regimen: DA-EPOCH + Rituxumab; Pharma adjuvant cycles count: 1.
- Treatments, Treatment 4: Therapy regimen: Recurrence; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: rituximab + gemcitabine + cisplatin; Pharma adjuvant cycles count: 2; Treatment best response: Clinical Progressive Disease.
